CCDI case PBBXJJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f13b6c76-c09e-4554-a0bc-00c8e5d3735a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,296 days).

Biospecimens (3 samples)
- Sample 0DJPCP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJPCV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJPDB: Tissue type: Tumor; Specimen type: Solid Tissue.
